Surgical pathology report (de-identified scan), TCGA case TCGA-99-AA5R, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-AA5R-01A (Primary Tumor).

[page 1 of 3]
ICD O-3

Adenocarcinoma NOS 8140/3

Site Lung, Lower Lobe C54.3
4/23/12/14

LUNG MALIGNANT
LUNG UNINVOLVED
BLOOD
—SERUM—
—PLASMA—
—BUFFY COAT—

Patient:

MRN:

Case:

yo black female

Collected date:

Result date:

Result title: Surgical Pathology Final Report

Electronically Signed by:

Clinical Information

The patient is a year old, [black] female with a lung nodule.

Frozen Section Diagnosis

MFS1: Left lower lobe, resection:

- Adenocarcinoma.

(Per

Gross Description

The specimen is received in thirteen containers each labeled with the patient's name and medical record number.

The first container is labeled "level IX lymph node". Received is an anthracotic fragment of tissue measuring 1.5 x 0.8 x 0.3 cm. It is serially sectioned and entirely submitted.

The second container is labeled "#2 - level VIII lymph node". Received is an anthracotic tan-yellow fragment of tissue measuring 0.5 x 0.4 x 0.2 cm, submitted in total.

The third container is labeled "#3 - level VII lymph node". Received is an anthracotic tan-gray fragment of soft tissue measuring 0.8 x 0.6 x 0.4 cm, trisected and submitted in total.

The fourth container is labeled "#4 - level XI lymph node". Received is an anthracotic fragment of tissue measuring 0.2 x 0.2 x 0.1 cm, submitted in total.

The fifth container is labeled "#5 - level V lymph node". Received is an anthracotic tan-gray fragment of soft tissue measuring 1.0 x 0.7 x 0.5 cm, bisected and submitted in total.

The sixth container is labeled "#6 - level VI lymph node". Received is a tan-yellow and focally anthracotic fragment of tissue measuring 0.6 x 0.3 x 0.3 cm, submitted in total.

The seventh container is labeled "#7 - level XI lymph node". Received is an anthracotic fragment of tissue measuring 0.4 x 0.4 x 0.3 cm, submitted in total.

The eighth container is labeled "#8 - level X lymph node". Received is an anthracotic fragment of tissue measuring 0.7 x 0.4 x 0.3 cm, submitted in total.

The ninth container is labeled "#9 - level XIII lymph node". Received is an irregularly shaped anthracotic fragment of tissue measuring 1.0 x 0.7 x 0.3 cm, trisected and submitted in total.

The tenth container is labeled "#10 - level XI lymph node". Received are two anthracotic fragments of tissue ranging from 0.2 up to 0.5 cm, submitted in total.

The eleventh container is labeled "#11 - level X lymph node". Received is a single anthracotic fragment of tissue measuring 1.0 x 0.6 x 0.5 cm, bisected and submitted in total.

The twelfth container is labeled "#12 - level X lymph node". Received is an irregularly shaped anthracotic fragment of tissue measuring 1.2 x 0.6 x 0.4 cm that is trisected and submitted in total.

[page 2 of 3]
The thirteenth container is labeled "#13 - left lower lobe". Received is a lobectomy specimen consistent with the left lower lobe measuring 18.0 x 9.0 x 3.3 cm in greatest dimensions. The pleural surface is tan-pink and shows moderate to severe anthracotic pigmentation. There is a staple line noted across the hilum of the lung revealing unremarkable bronchial and vascular structures. The bronchi are lined by tan-pink glistening mucosa without distinct gross lesion.

Located 2.5 cm from the bronchial resection margin, there is an intramural tan gritty nodule measuring 1.2 cm in greatest dimensions. This nodule is surrounded by red-brown spongy pulmonary parenchyma. A representative section of this nodule is submitted for frozen section as MFS1. The remaining lung reveals spongy and moderately anthracotic pulmonary parenchyma and reveals no other mass lesion. There are no other gross lesions identified. The remaining tumor is submitted for permanent section while a portion of tumor is submitted for frozen.

Block Summary

A1- Level IX lymph node.
B1- Level VIII lymph node.
C1- Level VII lymph node.
D1- Level XI lymph node.
E1- Level V lymph node.
F1- Level VI lymph node.
G1- Level XI lymph node.
H1- Level X lymph node.
I1- Level XIII lymph node.
J1- Level XI lymph node.
K1- Level X lymph node.
L1- Level X lymph node.
M1- Left lower lobe mass.
M2- Bronchial and vascular shave margins left lower lobe.
M3- Small peribronchiolar lymph nodes.
M4- Remainder of left lower lobe mass.
M5- Uninvolved parenchyma.

Microscopic Description

A microscopic examination has been performed.

Diagnosis

(A) Lymph node, level IX, excision:

- Negative for malignancy.

(B) Lymph node, level VIII, excision:

- Negative for malignancy.

(C) Lymph node, level VII, excision:

- Negative for malignancy.

(D) Lymph node, level XI, excision:

- Negative for malignancy.

(E) Lymph node, level V, excision:

- Negative for malignancy.

(F) Lymph node, level VI, excision:

- Negative for malignancy.

[page 3 of 3]
(G) Lymph node, level XI, excision:
- Negative for malignancy.

(H) Lymph node, level X, excision:
- Negative for malignancy.

(I) Lymph node, level XIII, excision:
- Negative for malignancy.

(J) Lymph node, level XI, excision:
- Negative for malignancy.

(K) Lymph node, level X, excision:
- Negative for malignancy.

(L) Lymph node, level X, excision:
- Negative for malignancy.

(M) Lung, left lower lobe, lobectomy:
- Adenocarcinoma (1.2 cm), moderately differentiated.
- Pleura is not involve by tumor.
- Surgical margin negative for malignancy.
- Three peribronchial lymph nodes negative for malignancy (0/3).

(Electronically signed by)
Verified:

Synoptic Report

SPECIMEN: Lobe(s) of lung: left lower lobe

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Left

TUMOR SITE: Lower lobe

TUMOR SIZE: Greatest dimension: 1.2 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

VASCULAR MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma

LYMPH NODES: Present

PRIMARY TUMOR (pT): pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

Source: NCI Genomic Data Commons file bcd25544-6788-46c0-8c69-3531c1b76399 (TCGA-99-AA5R.5541B103-6FD2-4767-B914-8A5B58E86D0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).